Somatic mutation profile of tumor specimen TCGA-BJ-A2N9-01A (aliquot TCGA-BJ-A2N9-01A-11D-A18F-08) from TCGA case TCGA-BJ-A2N9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.2 years (15,411 days).
Specimen TCGA-BJ-A2N9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afaa4bd5-23aa-4441-a4b7-82e0bf717095.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A2N9-10A (Blood Derived Normal), aliquot TCGA-BJ-A2N9-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46b3b280-cf67-4108-92f6-937b5c81e0fd

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARVCF | c.2348T>C p.I783T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV52890766; called by muse, mutect2, varscan2
- FILIP1 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756540736, COSV52739270; called by muse, mutect2, varscan2
- MYH1 | c.3984+1G>T p.X1328_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV56856092; called by muse, mutect2
- SEC14L4 | c.424C>T p.L142= | Splice Region (SNP) | VAF 11/47 reads (23%) | catalogued as COSV55401336; called by muse, mutect2, varscan2
- SPOCK3 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs771214229, COSV62735154; called by muse, mutect2, varscan2
- UBR5 | c.5303C>T p.A1768V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV55298228; called by muse, mutect2, varscan2
- WDR45 | c.452G>T p.C151F (on ENST00000376372 / NM_001029896.2; = p.C152F on NM_007075.3) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV59876902; called by muse, mutect2, varscan2
